Surgical pathology report (de-identified scan), TCGA case TCGA-WB-A80V, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Erasmus MC, specimen TCGA-WB-A80V-01A (Primary Tumor).

Short descriptive translation of the pathology report as provided by the

Date:

Material received:

Material: Left adrenal gland

Macroscopic findings

Adrenal Tumor: A 11x10x3 cm specimen after adrenalectomy (131 g, formalin fixed). The lesion has been cut already. On the sectioned surface a 7 cm light brown tumor with vulnerable tissue pattern. At the side of the lesion normal adrenal cortex can be seen. The capsule cannot be finally judged due to the prior cutting.

refers to
specimen
being cut
during surgery.

Microscopy findings:

At HE, Iron EvG-staining normal adrenal tissue with encapsulated lesion. The tumor is formed by enlarged cells with a bale-like pattern, a granular eosinophilic cytoplasm and prominent nucleoli. The space between the tumor cell nests is filled with blood. The tumor is surrounded by a fibrous capsule. Vascular invasion is absent.

Diagnosis:

Pheochromocytoma of the adrenal gland, without lateralization. No suspicion for capsular or vascular invasion. Due to the prior cutting no final judgment can be achieved concerning extra-adrenal growth.

Translated by:

ICD-O-3

Pheochromocytoma NOS 8700/0
Site: (L) Adrenal gland NOS C74.9
JW 10/17/13

Source: NCI Genomic Data Commons file 8d738b13-56f1-4d6f-a573-f0f8be3117e7 (TCGA-WB-A80V.49772AB5-A4B9-4062-B095-7D9B1560C7CF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).